Somatic mutation profile of tumor specimen ALCH-B2UN-TTP1-A (aliquot ALCH-B2UN-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2UN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.2 years (23,801 days).
Specimen ALCH-B2UN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b541b39e-4e68-4352-b768-8ee11c267127.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2UN-NB1-A (Blood Derived Normal), aliquot ALCH-B2UN-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cce76ab5-e6e0-41d2-9987-959a50b30949

The open-access MAF lists 95 somatic variants for this specimen: 66 protein-altering or splice-affecting, 19 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 19, Nonsense Mutation 7, Intron 5, Splice Site 3, RNA 2, Frame Shift Del 2, 5'Flank 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 36/320 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.4177C>T p.R1393W | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs753160597, COSV57051858; called by muse, mutect2
- ABCC11 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 20/160 reads (13%) | catalogued as COSV100750639; called by muse, mutect2, varscan2
- ALOX15B | c.1681-2A>T p.X561_splice | Splice Site (SNP) | VAF 6/90 reads (7%) | catalogued as rs1472047603; called by muse, mutect2
- BRINP3 | c.2137C>T p.L713F | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs199932346; called by muse, mutect2, varscan2
- CACNA1I | c.6620C>T p.P2207L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs1031129335; called by muse, mutect2, varscan2
- CCDC186 | c.1459C>G p.L487V | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs958937227; called by muse, mutect2
- CRACD | c.236T>C p.M79T | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs375684843; called by muse, mutect2, varscan2
- DLX4 | c.110C>G p.P37R | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs376997322; called by muse, mutect2, varscan2
- DSC3 | c.1912C>G p.Q638E | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV64573513; called by muse, mutect2, varscan2
- FAM47A | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as COSV60496090; called by muse, mutect2, varscan2
- GCN1 | c.3311G>C p.R1104P | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV100324521, COSV56105012; called by mutect2, varscan2
- HSD17B11 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 46/422 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV64154634; called by muse, mutect2, varscan2
- KEAP1 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | catalogued as COSV50671678; called by muse, mutect2, varscan2
- KLHL11 | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.864); catalogued as rs201471518; called by muse, mutect2, varscan2
- LIMS2 | c.124G>T p.V42L (on ENST00000355119 / NM_001161403.3; = p.V66L on NM_017980.4) | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs769304903; called by muse, mutect2, varscan2
- LRRTM4 | c.503C>A p.S168* | Nonsense Mutation (SNP) | VAF 33/223 reads (15%) | catalogued as COSV69142537; called by muse, mutect2, varscan2
- MYH6 | c.5491G>T p.E1831* | Nonsense Mutation (SNP) | VAF 26/336 reads (8%) | catalogued as rs367834703; called by muse, mutect2
- PDCD11 | c.620G>C p.G207A | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63933619; called by muse, mutect2
- PGR | c.2587G>T p.V863F | Missense Mutation (SNP) | VAF 47/348 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.359); catalogued as COSV54814343; called by muse, mutect2, varscan2
- POLR2A | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.872); catalogued as COSV59494069; called by muse, mutect2, varscan2
- PXDNL | c.4331G>T p.G1444V | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs199528987, COSV62478392; called by mutect2, varscan2
- REM1 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV52429724, COSV52430042, COSV52430379; called by muse, mutect2, varscan2
- RUNX1 | c.884C>T p.S295L (on ENST00000344691 / NM_001001890.3; = p.S322L on NM_001754.5) | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV55874276; called by muse, mutect2
- SRPRB | c.345G>C p.L115F | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); catalogued as COSV71749076; called by muse, mutect2
- STK11 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 16/162 reads (10%) | catalogued as CM981865, COSV58820140; called by muse, mutect2
- THSD7A | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as COSV101448473; called by muse, mutect2, varscan2
- UGT2B28 | c.1447C>T p.L483F | Missense Mutation (SNP) | VAF 40/618 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs748410262; called by muse, mutect2
- UNC45B | c.1907G>A p.C636Y | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs764876939, COSV52093335; called by muse, mutect2, varscan2
- UNC5B | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs375741576; called by muse, mutect2, varscan2
- ZFPM2 | c.2084C>A p.T695N | Missense Mutation (SNP) | VAF 124/829 reads (15%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); catalogued as COSV65874477; called by muse, mutect2, varscan2
- APPL1 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 19/300 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- ARHGAP39 | c.597-2A>G p.X199_splice | Splice Site (SNP) | VAF 20/124 reads (16%) | called by muse, mutect2, varscan2
- ATAD2B | c.2990A>C p.E997A | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); called by muse, varscan2
- ATM | c.6527T>A p.L2176* | Nonsense Mutation (SNP) | VAF 116/664 reads (17%) | called by muse, mutect2, varscan2
- CSF1R | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- DISP3 | c.1217C>A p.P406H | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- DLEC1 | c.3505G>C p.E1169Q | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.201); called by muse, mutect2
- ESRP2 | c.2173G>T p.V725L (on ENST00000565858 / NM_001365264.1; = p.V715L on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ESYT1 | c.1355T>C p.L452S | Missense Mutation (SNP) | VAF 52/400 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- EYS | c.5960C>G p.T1987S | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- FAM135A | c.4222A>G p.K1408E (on ENST00000370479 / NM_001351599.1; = p.K1195E on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM83E | c.740T>A p.V247D | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GPATCH3 | c.130T>G p.F44V | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HAT1 | c.1157T>G p.M386R | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.187); called by muse, mutect2
- HSPG2 | c.2897A>C p.E966A | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- INTS3 | c.2389+1G>T p.X797_splice | Splice Site (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- LSP1 | c.564C>A p.S188R | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.012); called by muse, mutect2
- MAGEL2 | c.3085C>A p.Q1029K | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.442); called by muse, mutect2
- MBP | c.424C>T p.Q142* (on ENST00000355994 / NM_001025101.2; = p.Q9* on NM_002385.3) | Nonsense Mutation (SNP) | VAF 26/266 reads (10%) | called by muse, mutect2
- OR4K2 | c.191C>A p.T64N | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2
- OR52I2 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 46/504 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- PCDHGA1 | c.2410C>G p.P804A | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCXD3 | c.956C>G p.A319G | Missense Mutation (SNP) | VAF 50/338 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RGPD3 | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 30/616 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- RYR2 | c.6338T>C p.V2113A | Missense Mutation (SNP) | VAF 77/448 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- RYR2 | c.10808T>C p.F3603S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLC39A6 | c.2116G>A p.V706I | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); called by mutect2, varscan2
- SLC6A9 | c.563T>C p.V188A (on ENST00000360584 / NM_201649.4; = p.V134A on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- SUPT20HL2 | c.1882G>T p.V628L | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAS2R7 | c.692_693del p.V231Efs*40 | Frame Shift Del (DEL) | VAF 36/308 reads (12%) | called by pindel, varscan2
- TEX11 | c.238del p.A80Hfs*4 (on ENST00000344304; = p.A65Hfs*4 on NM_031276.3) | Frame Shift Del (DEL) | VAF 24/126 reads (19%) | called by mutect2, pindel, varscan2
- THSD7A | c.150G>T p.Q50H | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- TXNDC11 | c.538T>C p.Y180H | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- TYMP | c.1411T>G p.S471A | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2
- WBP11 | c.1879G>C p.D627H | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ABCA3 | c.2310G>T p.P770= | Silent (SNP) | VAF 30/591 reads (5%) | called by muse, mutect2
- BMX | c.204C>T p.L68= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as rs1316750430; called by muse, mutect2, varscan2
- CTBP1 | c.261G>A p.E87= | Silent (SNP) | VAF 14/135 reads (10%) | called by muse, mutect2
- HPR | c.735G>T p.V245= | Silent (SNP) | VAF 30/316 reads (9%) | called by muse, mutect2
- IL18RAP | c.1203G>A p.T401= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as rs201945830; called by muse, mutect2, varscan2
- ITIH1 | c.1392C>A p.A464= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- KHDRBS2 | c.447T>C p.S149= | Silent (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- MUC19 | c.72C>T p.Y24= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as rs1217321135; called by muse, mutect2
- NAA60 | c.465C>T p.F155= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as rs1442091808; called by muse, mutect2
- NOS1 | c.2712G>A p.V904= | Silent (SNP) | VAF 10/199 reads (5%) | called by muse, mutect2
- NPAS3 | c.1095A>G p.R365= (on ENST00000356141 / NM_001164749.2; = p.R333= on NM_022123.3) | Silent (SNP) | VAF 44/436 reads (10%) | catalogued as rs773805152; called by muse, mutect2
- OR4K2 | c.192C>A p.T64= | Silent (SNP) | VAF 16/287 reads (6%) | catalogued as rs1012372774, COSV53851277; called by muse, mutect2
- OTUD6A | c.600C>T p.Y200= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV57973362; called by muse, mutect2
- PDE1A | c.1326T>C p.P442= | Silent (SNP) | VAF 33/269 reads (12%) | called by muse, mutect2, varscan2
- PRAMEF20 | c.1110G>T p.L370= | Silent (SNP) | VAF 59/670 reads (9%) | called by muse, mutect2
- RGS12 | c.2823G>A p.A941= | Silent (SNP) | VAF 23/240 reads (10%) | catalogued as rs538053152; called by muse, mutect2, varscan2
- RNF38 | c.1285C>A p.R429= | Silent (SNP) | VAF 14/143 reads (10%) | called by muse, mutect2, varscan2
- SERTAD3 | c.210C>T p.R70= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- TRIM77 | c.306C>A p.L102= | Silent (SNP) | VAF 30/282 reads (11%) | called by muse, varscan2
- AC243919.1 | n.415+31A>G | Intron (SNP) | VAF 26/208 reads (13%) | catalogued as rs1306286296; called by mutect2, varscan2
- COL6A2 | c.1053+9C>A | Intron (SNP) | VAF 21/256 reads (8%) | called by muse, mutect2
- GNGT1 | c.-8G>T | 5'UTR (SNP) | VAF 33/266 reads (12%) | called by muse, mutect2, varscan2
- GRIP2 | c.857+48C>A | Intron (SNP) | VAF 20/188 reads (11%) | called by muse, mutect2, varscan2
- MAEA | chr4:1289887 G>T | 5'Flank (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2
- PKM | c.1141-463A>T | Intron (SNP) | VAF 51/469 reads (11%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.*307G>C | 3'UTR (SNP) | VAF 38/201 reads (19%) | called by muse, mutect2, varscan2
- PPY2P | n.274G>T | RNA (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2, varscan2
- TPK1 | c.185+1097G>T | Intron (SNP) | VAF 22/276 reads (8%) | called by muse, mutect2
- UBTFL2 | n.524C>G | RNA (SNP) | VAF 86/472 reads (18%) | called by muse, mutect2, varscan2
